Somatic mutation profile of tumor specimen TCGA-AG-3583-01A (aliquot TCGA-AG-3583-01A-01D-1989-10) from TCGA case TCGA-AG-3583, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IV; Age at diagnosis: 66.0 years (24,107 days).
Specimen TCGA-AG-3583-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93d1b415-2ce6-4a3f-8548-9dea92d38807.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3583-10A (Blood Derived Normal), aliquot TCGA-AG-3583-10A-01D-1989-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03a436ed-140c-4147-b6a2-f2413259711e

The open-access MAF lists 25 somatic variants for this specimen: 15 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 8, Nonsense Mutation 2, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPN10 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 93/202 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as rs368852606; called by muse, mutect2, varscan2
- DNAH7 | c.6950G>A p.R2317Q | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.453); catalogued as rs1262544571, COSV56750341, COSV56756852; called by muse, varscan2
- EPHB4 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777267049, COSV62268053; called by muse, mutect2, varscan2
- FIBCD1 | c.203T>C p.V68A | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV99446675; called by muse, mutect2, varscan2
- GRIK5 | c.1315G>T p.G439W | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99489937; called by muse, mutect2, varscan2
- MED26 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 73/180 reads (41%) | catalogued as COSV99659776; called by muse, mutect2, varscan2
- NBEAL1 | c.7024G>A p.G2342S | Missense Mutation (SNP) | VAF 126/372 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs772334477, COSV101355377; called by muse, mutect2, varscan2
- OR8U1 | c.634C>A p.L212M | Missense Mutation (SNP) | VAF 97/345 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.363); catalogued as COSV100163727, COSV56418571; called by muse, varscan2
- PKD2L2 | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 56/134 reads (42%) | catalogued as rs1447073455, COSV99295947, COSV99296090; called by muse, mutect2, varscan2
- RIMS2 | c.1838C>T p.S613L (on ENST00000666250 / NM_001348490.2; = p.S421L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.921); catalogued as COSV99157644; called by muse, mutect2, varscan2
- RIMS2 | c.3295G>A p.A1099T (on ENST00000666250 / NM_001348490.2; = p.A907T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/276 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.036); catalogued as rs751622966, COSV51650684; called by muse, varscan2
- RIN3 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 56/70 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99378401; called by muse, varscan2
- SLC22A10 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 110/333 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs751339017, COSV60421119; called by muse, mutect2, varscan2
- TMED1 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.879); catalogued as COSV99284021; called by muse, mutect2
- TNFSF9 | c.605G>C p.R202P | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.23); catalogued as COSV55539361, COSV99832310; called by muse, mutect2, varscan2
- A1BG | c.1471C>T p.L491= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs201773235, COSV99568120; called by muse, mutect2, varscan2
- CFAP251 | c.2937A>T p.S979= | Silent (SNP) | VAF 56/162 reads (35%) | catalogued as COSV99995686; called by muse, mutect2, varscan2
- FRY | c.3759C>T p.F1253= | Silent (SNP) | VAF 60/241 reads (25%) | catalogued as rs1215481196, COSV100968778; called by muse, mutect2
- HTT | c.310C>T p.L104= | Silent (SNP) | VAF 85/250 reads (34%) | catalogued as COSV100750364; called by muse, varscan2
- KIF7 | c.3072C>T p.I1024= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1031833576, COSV99176001; called by muse, mutect2
- SMPD3 | c.1113C>T p.A371= | Silent (SNP) | VAF 50/136 reads (37%) | catalogued as COSV99545240, COSV99546184; called by muse, mutect2, varscan2
- SSBP4 | c.624C>T p.S208= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as rs1460729411, COSV99525938; called by muse, mutect2, varscan2
- UBL7 | c.834G>A p.L278= | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as COSV100795340; called by muse, mutect2, varscan2
- NBPF7 | n.998G>A | RNA (SNP) | VAF 96/252 reads (38%) | called by muse, mutect2, varscan2
- SREBF1 | c.92-3057_92-3053del | Intron (DEL) | VAF 30/94 reads (32%) | called by mutect2, pindel, varscan2
